CPTAC case C3L-02984 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5718a50d-332c-4882-8736-2ca8989946dd

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1983; Vital status: Alive; Country of birth: Philippines.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 34.1 years (12,449 days); Year of diagnosis: 2017; Last known disease status: Tumor free; Days to last known disease status: 1,764 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,764 days (4.8 years).
   Pathology details: Greatest tumor dimension: 3 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 384 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,042 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,042 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,469 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,764 days (4.8 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 97.52 kg; Height: 172.72 cm; BMI: 32.69.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02984-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 76 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02984-22: Section location: Frontal Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02984-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 68 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02984-23: Section location: Frontal Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02984-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 59 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02984-21: Section location: Frontal Lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-02984-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -19 days; Initial weight: 16 mg; Time between excision and freezing: 24 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02984-25: Section location: Frontal Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3L-02984-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -19 days; Method of sample procurement: Blood Draw.
